Gene-level copy-number profile of tumor specimen TCGA-D3-A5GL-06A from TCGA case TCGA-D3-A5GL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.5 years (27,568 days).
Specimen TCGA-D3-A5GL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.1fb5eabe-9ce0-4858-80b1-932afaefec16.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A5GL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8eb27f10-a2f6-4ad0-b9b6-d18604356ef7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 10,408; copy number 2: 48,673; copy number 3: 531; copy number 4: 143; copy number 5: 18; copy number 7: 15; copy number 9: 6; copy number 14: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A5GL-06A-11D-A27J-01): tumor purity 0.78, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:29,192,774–29,955,405, 6 genes (within-gene range 0–2): ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 54 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,739,464–70,518,064, 6 genes, copy number 9 (within-gene range 1–9): MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2.
- chr12:68,674,371–70,637,440, 47 genes, copy number 5–14: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 5: FAHD2P1.

Autosomal genes at a single copy (total copy number 1): 8,028. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
